Somatic mutation profile of tumor specimen TCGA-AH-6897-01A (aliquot TCGA-AH-6897-01A-11D-1924-10) from TCGA case TCGA-AH-6897, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 48.0 years (17,536 days).
Specimen TCGA-AH-6897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ea0507f-32ae-4da6-8de2-50f31dc4c447.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6897-10A (Blood Derived Normal), aliquot TCGA-AH-6897-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b620119a-f119-47ab-806d-8544dcbb25f0

The open-access MAF lists 130 somatic variants for this specimen: 94 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 32, Nonsense Mutation 5, Splice Site 3, Intron 2, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 193/207 reads (93%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 66/111 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 26/30 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV67218877, COSV67231763; called by muse, mutect2, varscan2
- AGER | c.54G>A p.G18= | Splice Region (SNP) | VAF 21/69 reads (30%) | catalogued as rs372263884; called by muse, mutect2, varscan2
- AHNAK2 | c.7852G>A p.V2618I | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs199877699; called by muse, mutect2, varscan2
- AKAP12 | c.5321C>T p.S1774F | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV53581840; called by muse, mutect2, varscan2
- AMPH | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs367689186, COSV57737340; called by muse, mutect2, varscan2
- APC | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 100/181 reads (55%) | catalogued as COSV57326256, COSV57366632; called by muse, mutect2, varscan2
- APC | c.3544A>T p.K1182* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as CD021192, COSV57341394; called by muse, mutect2, varscan2
- ARHGEF28 | c.283A>T p.M95L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55269167; called by muse, mutect2, varscan2
- ARSJ | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV59538244, COSV59539724; called by muse, mutect2, varscan2
- ATP10A | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs759871370, COSV63523776; called by muse, mutect2, varscan2
- ATP12A | c.3011G>T p.W1004L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54522986; called by muse, mutect2, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs754310793, COSV52681762; called by pindel, varscan2
- CAND2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs947083661, COSV55994242, COSV99929084; called by muse, mutect2, varscan2
- CDH13 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs368685803; called by muse, mutect2, varscan2
- CENPJ | c.568+1G>A p.X190_splice | Splice Site (SNP) | VAF 35/131 reads (27%) | catalogued as COSV101121560; called by muse, mutect2, varscan2
- CMAS | c.479T>G p.M160R | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV57557514; called by muse, mutect2, varscan2
- CNTN3 | c.1557G>T p.L519F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV55173715; called by muse, mutect2, varscan2
- CORO1B | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58172340; called by muse, mutect2, varscan2
- CPNE6 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs534432936, COSV53746404; called by muse, mutect2, varscan2
- CUBN | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs770625165, COSV64726686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCC | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762821495, COSV71427449; called by muse, mutect2, varscan2
- DHTKD1 | c.2685G>T p.L895F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.886); catalogued as COSV53806763; called by muse, mutect2, varscan2
- DNAH17 | c.3790C>T p.P1264S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs189791030; called by muse, mutect2, varscan2
- DNAH8 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59478640; called by muse, mutect2, varscan2
- DNAI4 | c.530+1G>A p.X177_splice | Splice Site (SNP) | VAF 39/95 reads (41%) | catalogued as COSV64019921; called by mutect2, varscan2
- FAM186B | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs376783093; called by muse, mutect2, varscan2
- FAM78B | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100597454, COSV57982176; called by muse, mutect2, varscan2
- FAT3 | c.11812G>A p.V3938M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1053068067, COSV53115727, COSV53140989; called by muse, mutect2, varscan2
- FAT4 | c.6172T>A p.Y2058N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV58707616; called by muse, mutect2, varscan2
- FBLN2 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as rs200141144; called by muse, mutect2, varscan2
- FCHO2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV59277036; called by muse, mutect2, varscan2
- FOXO3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59631142; called by muse, mutect2, varscan2
- GLB1 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs1375909576, COSV56567808; called by muse, mutect2, varscan2
- GRIK2 | c.1619T>C p.I540T | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100028554; called by muse, varscan2
- GRIK2 | c.1663T>C p.F555L | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV59770049; called by muse, varscan2
- GRK6 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100587005; called by muse, mutect2, varscan2
- HECW1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759660521, COSV67839496; called by muse, mutect2, varscan2
- HSPA9 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as rs372075340; called by muse, mutect2, varscan2
- IL18RAP | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756620639, COSV51825668; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KIAA0100 | c.6466A>G p.T2156A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99972276; called by muse, mutect2, varscan2
- KIF1A | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs376012799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA6 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV65362061; called by muse, mutect2, varscan2
- KRCC1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV61252239; called by muse, mutect2, varscan2
- MAST2 | c.3928G>A p.G1310S | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs1379760012, COSV100788794, COSV63621363; called by muse, mutect2, varscan2
- MLC1 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs281875313, CM061849, COSV61118756; called by muse, mutect2, varscan2
- MOS | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV61336706; called by muse, mutect2, varscan2
- MRTO4 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57674619; called by muse, mutect2, varscan2
- MYOF | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555130930, COSV63710374; called by muse, mutect2, varscan2
- NEU1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs761724054, CM145912, COSV99999212; called by muse, mutect2, varscan2
- NRXN1 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV101277723, COSV68045545; called by muse, mutect2, varscan2
- OR4C46 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as rs141039879, COSV60221138; called by muse, mutect2, varscan2
- OR51M1 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV60784324, COSV60785041; called by muse, mutect2, varscan2
- PKNOX1 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52339686; called by muse, mutect2, varscan2
- PREX2 | c.4333A>G p.N1445D | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV55771082, COSV55797631; called by muse, mutect2, varscan2
- PYGO1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as rs200070647, COSV100114782; called by muse, mutect2, varscan2
- RASGRF2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV54139072; called by muse, mutect2, varscan2
- RGL1 | c.1666G>A p.V556M (on ENST00000360851 / NM_001297672.2; = p.V591M on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766605243, COSV58995842; called by muse, mutect2, varscan2
- RIMS1 | c.1903A>T p.I635F | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53483226; called by muse, mutect2, varscan2
- RNASE4 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59013145; called by muse, mutect2, varscan2
- RNF103 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52896940; called by muse, mutect2, varscan2
- RYR2 | c.9523C>G p.L3175V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV63712182; called by muse, mutect2, varscan2
- SACS | c.12269A>T p.H4090L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV66546564; called by muse, mutect2, varscan2
- SCAPER | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV57753558; called by muse, mutect2, varscan2
- SEMA3E | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs777910966, COSV100317685, COSV57107615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A4 | c.1186T>C p.W396R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV54838958; called by mutect2, varscan2
- SPECC1 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs759943499, COSV54961254; called by muse, mutect2, varscan2
- SRRM2 | c.5864G>A p.R1955H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1183948226, COSV57080159; called by muse, mutect2, varscan2
- TAPT1 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as rs756498331, COSV58824468; called by muse, mutect2, varscan2
- TBCD | c.2114G>A p.W705* | Nonsense Mutation (SNP) | VAF 47/309 reads (15%) | catalogued as COSV62805631, COSV62807467; called by muse, mutect2, varscan2
- TENM4 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs769818383, COSV53661723; called by muse, mutect2, varscan2
- TFAP2B | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as COSV53831178; called by muse, mutect2, varscan2
- TMEM94 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 227/389 reads (58%) | catalogued as rs191852169; called by muse, mutect2, varscan2
- TMPRSS5 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV55426205; called by muse, mutect2, varscan2
- TNFRSF19 | c.1012A>G p.N338D | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1415755056, COSV50320297; called by muse, mutect2, varscan2
- TRIM24 | c.2728C>T p.R910C (on ENST00000343526 / NM_015905.3; = p.R876C on NM_003852.4) | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58968992; called by muse, mutect2, varscan2
- TWF1 | c.378G>A p.K126= | Splice Region (SNP) | VAF 16/67 reads (24%) | catalogued as COSV57301843; called by muse, mutect2, varscan2
- UBQLNL | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66494522; called by muse, mutect2, varscan2
- USP37 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV51447130; called by muse, mutect2, varscan2
- ZBED9 | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as COSV101509359, COSV71729267; called by muse, mutect2, varscan2
- ZDHHC21 | c.253+1G>T p.X85_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV66615281; called by muse, mutect2, varscan2
- ZNF516 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436759669, COSV71587056; called by muse, mutect2, varscan2
- ZNF536 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62826032; called by muse, mutect2, varscan2
- ZNF551 | c.619A>C p.S207R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56595006; called by mutect2, varscan2
- ZNF648 | c.289A>T p.M97L | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60572710; called by muse, mutect2, varscan2
- ACACA | c.1152T>A p.F384L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFHC1 | c.1301_1302del p.K434Rfs*19 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- GPR179 | c.6705A>G p.I2235M (on ENST00000621958; = p.I2234M on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SIN3A | c.563dup p.G189Wfs*5 | Frame Shift Ins (INS) | VAF 47/195 reads (24%) | called by mutect2, pindel, varscan2
- TRIM24 | c.3025dup p.R1009Kfs*10 (on ENST00000343526 / NM_015905.3; = p.R975Kfs*10 on NM_003852.4) | Frame Shift Ins (INS) | VAF 53/139 reads (38%) | called by mutect2, pindel, varscan2
- USP24 | c.519_521del p.R174del | In Frame Del (DEL) | VAF 28/59 reads (47%) | called by mutect2, pindel, varscan2
- ADAM33 | c.1350G>A p.S450= | Silent (SNP) | VAF 102/186 reads (55%) | catalogued as COSV62936833; called by muse, mutect2, varscan2
- CSMD3 | c.10722T>C p.N3574= (on ENST00000297405 / NM_001363185.1; = p.N3405= on NM_052900.3) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1251327403, COSV52310660; called by muse, mutect2, varscan2
- DSG1 | c.690C>T p.Y230= | Silent (SNP) | VAF 43/48 reads (90%) | catalogued as rs781133396, COSV57133770; called by muse, mutect2, varscan2
- EEF2K | c.261C>T p.H87= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs200566569, COSV53786836; called by muse, mutect2, varscan2
- EGR4 | c.963C>T p.N321= (on ENST00000545030; = p.N218= on NM_001965.4) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV71532323; called by muse, mutect2, varscan2
- FBXL20 | c.1230C>T p.H410= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs143298147; called by muse, mutect2, varscan2
- FIGN | c.1974G>A p.R658= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV60771618; called by muse, mutect2, varscan2
- FREM2 | c.339C>T p.D113= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV54832485; called by muse, mutect2, varscan2
- GP1BA | c.336G>A p.G112= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as COSV56700797; called by muse, mutect2, varscan2
- ITPRID2 | c.1401C>T p.F467= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs763088774, COSV100238634; called by muse, mutect2, varscan2
- KIF21B | c.3417C>T p.P1139= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59765899; called by muse, mutect2, varscan2
- LMAN1L | c.396C>T p.D132= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs1438273756, COSV59002311, COSV59003641; called by muse, mutect2, varscan2
- LRWD1 | c.1635G>A p.A545= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs761553328, COSV53000966; called by muse, mutect2, varscan2
- MYBPC3 | c.2178C>T p.R726= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs370676057; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPR3 | c.903A>C p.S301= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99423707; called by muse, mutect2, varscan2
- OR2AG2 | c.186G>T p.L62= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV58456207; called by muse, mutect2, varscan2
- OR2T34 | c.642C>T p.T214= | Silent (SNP) | VAF 42/241 reads (17%) | catalogued as rs749789578, COSV60901708; called by muse, varscan2
- PCDH18 | c.1171C>T p.L391= | Silent (SNP) | VAF 51/92 reads (55%) | catalogued as COSV61271929; called by muse, mutect2, varscan2
- PCDHA3 | c.1761G>A p.A587= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs1213340646, COSV100793851, COSV63543015; called by muse, mutect2, varscan2
- PTPRD | c.2094G>A p.E698= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV61980179, COSV61988903; called by muse, mutect2, varscan2
- RAD23A | c.1086C>T p.D362= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs756392712, COSV57539165; called by muse, mutect2, varscan2
- RSPH14 | c.627G>A p.K209= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs1467000280, COSV53271963; called by muse, mutect2, varscan2
- SCN5A | c.5799C>A p.G1933= (on ENST00000333535 / NM_198056.3; = p.G1932= on NM_000335.5) | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV61140093; called by muse, mutect2, varscan2
- SEC16A | c.3960C>T p.Y1320= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs368962662; called by muse, mutect2, varscan2
- SETD1A | c.2835C>T p.D945= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs766001323, COSV52692175; called by muse, mutect2, varscan2
- STK32B | c.810C>T p.R270= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs745429127, COSV51512012; called by muse, varscan2
- TBCD | c.1035C>T p.T345= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs746230028, COSV100832707, COSV62797211; called by muse, mutect2, varscan2
- TFEB | c.402C>T p.S134= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs777139304, COSV57826773; called by muse, mutect2, varscan2
- TNS3 | c.1584C>T p.N528= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs770876695, COSV60798965; called by muse, mutect2, varscan2
- UNC45B | c.2329C>T p.L777= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV52100443; called by muse, mutect2, varscan2
- UNC5B | c.1638C>T p.S546= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs374710244; called by muse, mutect2, varscan2
- ZBTB48 | c.1860C>T p.D620= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs753577837, COSV66554229; called by muse, mutect2, varscan2
- ADAD2 | c.419-245C>T | Intron (SNP) | VAF 21/55 reads (38%) | catalogued as rs749673827, COSV51893938; called by muse, mutect2, varscan2
- HMGB1P1 | n.70C>T | RNA (SNP) | VAF 15/40 reads (38%) | catalogued as rs758693908; called by muse, mutect2, varscan2
- LINC01588 | n.3982C>T | RNA (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.444+7538G>A | Intron (SNP) | VAF 29/166 reads (17%) | catalogued as rs1289929060, COSV51399065; called by muse, mutect2
